Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3O9, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3O9-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender:

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #

Collected:

Received:

Reported:

Review (circle):		

Specimen(s) Received

1. Parathyroid: Right Lower
2. Thyroid ;Right hemithyroid stitch marks upper pole

Pw TSS on 3/30/13, TCGA tumor is
100% follicular variant. hu

Diagnosis

1. No pathological diagnosis: Parathyroid, right lower, biopsy.
2. Multifocal papillary carcinoma, dominant oncocytic follicular variant 4.5 cm, right; focal mild reactive C-cell hyperplasia: Thyroid
No pathological diagnosis: Lymph nodes, 2, isthmus
-Right hemithyroidectomy specimen. See Comment.

Comment

2. Although the clinical significance of focal mild C-cell hyperplasia is not well known in a hemithyroidectomy specimen, the features suggest a reactive phenomenon in this case. This case has been seen in consultation with Dr. [redacted] and he agrees with the interpretation and diagnosis.

1CD-0-3

Synoptic Data

CQEF: carcinoma, papillary, follicular variant 8340/3

8340/3

Path: carcinoma, papillary, follicular variant, and
oxyphilic 8342/3 - code to highest (8342/3)

Size: thyroid, NOS C73.9

hu
2/5/12

Procedure:

Received:

Specimen Integrity:

Specimen Size:

Right hemithyroidectomy

Fresh

Intact

Right lobe:

4.5 cm

3.2 cm

2.5 cm

Isthmus +/- pyramidal lobe:

2.9 cm

2.3 cm

0.8 cm

Specimen Weight:

27.7 g

Tumor Focality:

Multifocal, ipsilateral

Multifocal, midline (isthmus)

DOMINANT TUMOR

Tumor Laterality:

Right lobe

Tumor Size:

Greatest dimension: 4.5cm

Additional dimension: 3.2 cm

Additional dimension: 2.5 cm

[page 2 of 3]
Surgical Pathology Consultation Report

Histologic Type: Papillary carcinoma, follicular variant
Papillary carcinoma, oncocytic or oxyphilic variant
Follicular architecture
Oncocytic or oxyphilic cytomorphology

Histologic Grade: Not applicable

Margins: Margins uninvolved by carcinoma

Tumor Capsule: Totally encapsulated

Tumor Capsular Invasion: Present, extent minimal

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

----- SECOND TUMOR -----

Tumor Laterality: Isthmus

Tumor Size: Greatest dimension: 0.05cm

Histologic Type: Papillary carcinoma, follicular variant
Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
Follicular architecture
Classical cytomorphology

Histologic Grade: Not applicable

Margins: Margins uninvolved by carcinoma

Tumor Capsule: None

Tumor Capsular Invasion: Not identified

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Not identified

Extrathyroidal Extension: Not identified

TNM Descriptors: m (multiple primary tumors)

Primary Tumor (pT): pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension
(eg, extension to sternothyroid muscle or perithyroid soft tissues)

Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis
Number of regional lymph nodes examined: 2
Number of regional lymph nodes involved: 0

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: Thyroiditis, palpation
C-cell hyperplasia

Ancillary Studies: Type: IHC
Results: Calcitonin stains focal mild reactive C-cell hyperplasia.

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

1. The specimen labeled with the patient's name and as "RT Lower Parathyroid" contains a piece of tissue that measures 0.4 x 0.3 x 0.1 cm. It is frozen for intraoperative consultation.

1A frozen tissue resubmitted

2. The specimen labeled with the patient's name and as "RT Hemithyroid, Stitch Marks Upper Pole", consists of a right hemithyroidectomy specimen that is oriented with a suture and weighs 27.7 g. The lobe measures 4.5 cm SI x 3.2 cm ML x 2.5 cm AP and the isthmus measures 2.9 SI x 2.3 cm ML x 0.8 cm AP. The external surfaces have fibrous adhesions and are painted with Silver nitrate. No parathyroid glands and/or lymph nodes are identified grossly. The entire lobe contains a well delineated partly cystic containing brown fluid nodule(s) that measure 4.5 cm SI x 3.2 cm ML x 2.5 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted in toto

[page 3 of 3]
Surgical Pathology Consultation Report

2A-H lobe, superior to inferior (D-E section bisected)
2I-L isthmus

Quick Section Diagnosis

1. Right lower parathyroid, qs: - Parathyroid tissue identified
OR called

Source: NCI Genomic Data Commons file 720d0663-9189-4429-a374-c5f4e626fd86 (TCGA-EM-A3O9.44788DFC-8228-4220-A9DA-66AD8126C43B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).